Somatic mutation profile of tumor specimen TCGA-77-6845-01A (aliquot TCGA-77-6845-01A-11D-1945-08) from TCGA case TCGA-77-6845, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,321 days).
Specimen TCGA-77-6845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 485938c6-7e4e-467a-a5fe-0ce08d5dfd1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-6845-10A (Blood Derived Normal), aliquot TCGA-77-6845-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e3360de-f389-4bda-8fc8-d4fab835266f

The open-access MAF lists 256 somatic variants for this specimen: 189 protein-altering or splice-affecting, 59 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 59, Nonsense Mutation 9, Frame Shift Del 8, RNA 6, In Frame Del 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, Intron 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- ABCA13 | c.11270G>T p.W3757L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV101446890; called by muse, mutect2, varscan2
- ABCA13 | c.11271G>T p.W3757C | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101446891; called by muse, mutect2, varscan2
- ABL1 | c.2656G>T p.G886W | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100583679; called by muse, mutect2, varscan2
- ABRAXAS2 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100044904; called by muse, varscan2
- ADAMTS20 | c.2995C>A p.H999N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV101166147, COSV67128635; called by muse, mutect2, varscan2
- ADCY1 | c.2941G>A p.V981I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.527); catalogued as rs1481178944, COSV99811644; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV100416362; called by muse, mutect2, varscan2
- APOB | c.13348G>A p.E4450K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as rs866063436, COSV51953846; called by muse, mutect2, varscan2
- ARHGAP31 | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99956837; called by muse, mutect2, varscan2
- ATM | c.3065T>C p.I1022T | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99588671; called by muse, mutect2, varscan2
- ATP1A3 | c.2515C>A p.P839T (on ENST00000545399 / NM_001256214.2; = p.P826T on NM_152296.5) | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100132123; called by muse, mutect2, varscan2
- BRCA1 | c.4961T>A p.V1654E | Missense Mutation (SNP) | VAF 115/134 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100523658; called by muse, mutect2, varscan2
- C10orf71 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV100109959, COSV60505874; called by muse, mutect2, varscan2
- C12orf40 | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs754348818, COSV100209821; called by muse, varscan2
- CACNA1D | c.3998G>T p.G1333V (on ENST00000350061 / NM_001128840.3; = p.G1353V on NM_000720.4) | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs760925543, COSV99857301; called by muse, mutect2, varscan2
- CACNA2D4 | c.1096A>T p.M366L | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV99765361; called by muse, mutect2, varscan2
- CAPN13 | c.494G>A p.W165* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99700001; called by muse, mutect2, varscan2
- CBLL1 | c.283-2A>T p.X95_splice | Splice Site (SNP) | VAF 46/112 reads (41%) | catalogued as COSV99755520; called by muse, mutect2, varscan2
- CCDC102B | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100102903; called by muse, mutect2
- CCNT2 | c.1682A>G p.K561R | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99750368; called by muse, mutect2, varscan2
- CDH13 | c.2028G>C p.R676S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99224179, COSV99224502; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1778C>G p.T593S (on ENST00000357886 / NM_001365728.1; = p.T579S on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99866749; called by muse, mutect2, varscan2
- CEP126 | c.2907G>C p.Q969H | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV54823327, COSV99680839; called by muse, mutect2, varscan2
- CEP89 | c.666A>T p.P222= | Splice Region (SNP) | VAF 270/303 reads (89%) | catalogued as COSV99993273; called by muse, mutect2, varscan2
- CHAT | c.524T>A p.L175H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV100339950; called by muse, mutect2, varscan2
- CLEC9A | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs369586402; called by muse, mutect2, varscan2
- CMKLR1 | c.641A>G p.Y214C (on ENST00000312143 / NM_001142344.2; = p.Y212C on NM_004072.3) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.704); catalogued as rs200130577, COSV56439815; called by muse, mutect2, varscan2
- CNTLN | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52080545, COSV99263383; called by muse, mutect2, varscan2
- CNTN1 | c.1552G>T p.V518F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61638430; called by muse, mutect2, varscan2
- CNTNAP5 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1257323115, COSV101443244; called by muse, mutect2, varscan2
- COL19A1 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750042587, COSV100505807, COSV59585071; called by muse, mutect2
- COL9A1 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294391; called by muse, mutect2, varscan2
- COLEC11 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 78/135 reads (58%) | catalogued as COSV52596121; called by muse, mutect2, varscan2
- CSMD3 | c.3707G>C p.R1236T (on ENST00000297405 / NM_001363185.1; = p.R1132T on NM_052900.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV52225719, COSV52227624, COSV52294338; called by mutect2, varscan2
- CSMD3 | c.1594G>A p.V532I (on ENST00000297405 / NM_001363185.1; = p.V428I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV52161787; called by muse, mutect2, varscan2
- CTNNA2 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63603306; called by muse, mutect2, varscan2
- CTNNA2 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100559833; called by muse, mutect2, varscan2
- DCBLD2 | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99504663; called by muse, mutect2, varscan2
- DGKG | c.1785C>A p.F595L | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99402927; called by muse, mutect2
- DNAH8 | c.7949C>G p.T2650S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100544093; called by muse, mutect2, varscan2
- DSCAML1 | c.2349G>T p.W783C (on ENST00000321322; = p.W723C on NM_020693.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100355353, COSV58400440; called by muse, mutect2, varscan2
- DSCAML1 | c.2348G>T p.W783L (on ENST00000321322; = p.W723L on NM_020693.4) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100355355; called by muse, mutect2, varscan2
- DYRK2 | c.343G>A p.G115S (on ENST00000344096 / NM_006482.3; = p.G42S on NM_003583.4) | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as COSV100165245; called by muse, mutect2, varscan2
- E2F7 | c.1722T>A p.D574E | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100523402; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 261/328 reads (80%) | SIFT tolerated (0.69); PolyPhen benign (0.169); catalogued as COSV100668510, COSV62567072; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1186G>T p.G396C (on ENST00000361735 / NM_015935.5; = p.G310C on NM_014955.3) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100675808; called by muse, mutect2, varscan2
- EMC4 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50784617, COSV99970831; called by muse, mutect2, varscan2
- ERCC6 | c.3409A>G p.K1137E | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100875820; called by muse, mutect2, varscan2
- ERF | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV99724568; called by muse, mutect2, varscan2
- ESS2 | c.634A>T p.S212C | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99350732; called by muse, mutect2, varscan2
- FBN2 | c.6553G>T p.G2185C | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52509130; called by muse, mutect2, varscan2
- FHL5 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs769543900, COSV100459268; called by muse, mutect2, varscan2
- FIGNL1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV63553887; called by muse, mutect2, varscan2
- FOLH1 | c.920+2T>A p.X307_splice | Splice Site (SNP) | VAF 44/114 reads (39%) | catalogued as COSV99922953; called by muse, mutect2, varscan2
- GDAP2 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101031895; called by muse, mutect2, varscan2
- GORASP2 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143373773, COSV99304452; called by muse, mutect2, varscan2
- IDI1 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV101191179; called by muse, mutect2, varscan2
- IL36G | c.159A>T p.P53= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99381118; called by muse, mutect2, varscan2
- INHBC | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV100547972; called by muse, mutect2, varscan2
- IPP | c.1244A>G p.N415S | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100739452; called by muse, mutect2, varscan2
- IRAK3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706047; called by muse, mutect2, varscan2
- IRF6 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as CM022395, COSV100883930, COSV65420491; called by muse, mutect2, varscan2
- ITIH6 | c.1731C>G p.F577L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV54488151, COSV99513061; called by muse, mutect2, varscan2
- ITPR1 | c.5089G>A p.D1697N (on ENST00000354582; = p.D1691N on NM_001168272.2) | Missense Mutation (SNP) | VAF 250/316 reads (79%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs768509616, COSV56985077; called by muse, mutect2, varscan2
- KCTD5 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100069515; called by muse, mutect2, varscan2
- KEAP1 | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV50268599, COSV99407545; called by muse, mutect2, varscan2
- KIAA1109 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs779054376, COSV52671864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF9 | c.590A>T p.H197L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009546; called by muse, mutect2, varscan2
- KRT78 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100467206; called by muse, mutect2, varscan2
- LCE1A | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100632053, COSV58727934; called by muse, mutect2, varscan2
- LCE1C | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 87/125 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908427; called by muse, mutect2, varscan2
- LDB2 | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.665); catalogued as COSV100453176; called by muse, mutect2, varscan2
- LDLRAP1 | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV100974706; called by muse, mutect2, varscan2
- LRCH3 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100604995; called by muse, mutect2, varscan2
- LRP5 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV99591673; called by muse, mutect2, varscan2
- MDK | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as rs751840359, COSV100551246; called by muse, varscan2
- MMP21 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100523356; called by muse, mutect2, varscan2
- MMRN1 | c.3495T>G p.D1165E | Missense Mutation (SNP) | VAF 79/99 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306811; called by muse, mutect2, varscan2
- MRC1 | c.1970G>A p.S657N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs558553788; called by muse, mutect2
- MTMR12 | c.1881G>C p.L627F | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99373469; called by muse, mutect2
- MUC17 | c.8755C>T p.P2919S | Missense Mutation (SNP) | VAF 203/502 reads (40%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.857); catalogued as rs753731770, COSV100072472; called by muse, mutect2, varscan2
- MYCT1 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100924050; called by muse, mutect2, varscan2
- MYF5 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 45/163 reads (28%) | catalogued as COSV57357227, COSV99953074; called by muse, mutect2, varscan2
- MYOF | c.5235G>C p.R1745S | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100825495; called by muse, mutect2, varscan2
- NEDD1 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99900891; called by muse, mutect2, varscan2
- NELL2 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100419169, COSV100420785; called by muse, mutect2, varscan2
- NF2 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV100097892, COSV58528147; called by muse, mutect2, varscan2
- NKAIN1 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV99744451; called by muse, mutect2, varscan2
- NLRC4 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.029); catalogued as COSV100707307; called by muse, mutect2
- NOBOX | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56193950, COSV56194458; called by muse, mutect2, varscan2
- NOD2 | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 69/108 reads (64%) | catalogued as COSV100318353; called by muse, mutect2, varscan2
- NOSTRIN | c.990C>A p.Y330* (on ENST00000317647 / NM_001039724.4; = p.Y252* on NM_052946.3) | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV100473308; called by muse, mutect2, varscan2
- NTRK3 | c.1885C>T p.L629F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62312072; called by muse, mutect2, varscan2
- NUAK1 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99776817; called by muse, mutect2, varscan2
- NXF3 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 101/110 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV101221910; called by muse, mutect2, varscan2
- NXPE4 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV100970355; called by muse, mutect2, varscan2
- OLFML2B | c.2107C>T p.H703Y | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99668220; called by muse, mutect2, varscan2
- OR1J2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as rs200185396, COSV100093162; called by muse, mutect2, varscan2
- OR1L3 | c.382A>T p.N128Y | Missense Mutation (SNP) | VAF 106/147 reads (72%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as COSV100506222; called by muse, mutect2, varscan2
- OR1L8 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100508479; called by muse, mutect2, varscan2
- OR1S2 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100224072; called by muse, mutect2, varscan2
- OR2T6 | c.43A>T p.M15L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100861518, COSV63215716; called by muse, mutect2, varscan2
- OR4D5 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100189823; called by muse, mutect2, varscan2
- OR4N5 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 215/542 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100374069; called by muse, mutect2, varscan2
- OR5H15 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100736640; called by muse, mutect2
- OR6B1 | c.787A>T p.I263F | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV101281644; called by muse, mutect2
- OR6S1 | c.634T>A p.S212T | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV100289323; called by muse, mutect2, varscan2
- OR8B3 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100660385, COSV63541581; called by muse, mutect2, varscan2
- OR8D2 | c.521T>G p.V174G | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100658946; called by muse, mutect2, varscan2
- PAPPA | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100073407; called by muse, mutect2, varscan2
- PAPPA2 | c.2210A>G p.H737R | Missense Mutation (SNP) | VAF 146/214 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866680; called by muse, mutect2, varscan2
- PCDH9 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 102/115 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV100119458; called by muse, mutect2, varscan2
- PCDHGA2 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 90/118 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99534205; called by muse, mutect2, varscan2
- PGAM2 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99803586; called by muse, mutect2, varscan2
- PIFO | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100868604; called by muse, mutect2, varscan2
- PIK3R2 | c.1108A>T p.R370W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99717300; called by muse, mutect2, varscan2
- PKHD1L1 | c.8090G>A p.G2697D | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as rs755675853, COSV101005800; called by muse, mutect2, varscan2
- PLN | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); catalogued as COSV100682523; called by muse, mutect2, varscan2
- PLXDC1 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100195130, COSV59551494; called by muse, mutect2, varscan2
- POGK | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as COSV100902448; called by muse, mutect2, varscan2
- PRDM15 | c.3567G>C p.Q1189H | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV99519643; called by muse, mutect2, varscan2
- PRDM9 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99690122; called by muse, mutect2
- PREX1 | c.4573A>G p.T1525A | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs759964904, COSV100906135; called by muse, mutect2, varscan2
- PRKCB | c.1390T>A p.Y464N | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100333055; called by muse, mutect2, varscan2
- PRSS54 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs562622597, COSV99540807; called by muse, mutect2, varscan2
- PTPRM | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV100156188; called by muse, mutect2, varscan2
- RANBP2 | c.5007G>C p.W1669C | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311672; called by muse, varscan2
- REC8 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.71); catalogued as COSV100268934; called by muse, mutect2, varscan2
- RGL2 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV101004745; called by muse, mutect2, varscan2
- RGS22 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752894416, COSV100693115; called by muse, mutect2, varscan2
- RGS4 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100905540; called by muse, mutect2
- RNASE8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100373496; called by muse, mutect2, varscan2
- RPAP1 | c.2135A>G p.H712R | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV100427061; called by muse, mutect2, varscan2
- SEC63 | c.2197A>T p.I733L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100938345; called by muse, mutect2, varscan2
- SERGEF | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56383026, COSV99787073; called by muse, mutect2, varscan2
- SERINC1 | c.93T>A p.S31R | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV100305126; called by muse, mutect2, varscan2
- SERPINA12 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV100369624; called by muse, mutect2, varscan2
- SF1 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV99918107; called by muse, mutect2, varscan2
- SF3B6 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV99272653; called by muse, mutect2, varscan2
- SLC45A2 | c.1267T>C p.S423P | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99672498; called by muse, mutect2, varscan2
- SLC45A2 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs1364628131, COSV99672500; called by muse, mutect2, varscan2
- SLC9A4 | c.1748G>T p.R583I | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99762851; called by muse, mutect2, varscan2
- SLCO1C1 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99858799; called by muse, mutect2, varscan2
- SORCS1 | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV99544732, COSV99548010; called by muse, varscan2
- SPART | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 124/157 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768631; called by muse, mutect2, varscan2
- SPTBN1 | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442148; called by muse, mutect2, varscan2
- STIL | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as COSV99680754; called by muse, mutect2, varscan2
- TEK | c.1945A>G p.N649D | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs760995397, COSV101193322; called by muse, mutect2, varscan2
- TERF2 | c.618T>G p.I206M | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as COSV99651383; called by muse, mutect2, varscan2
- TESPA1 | c.1381C>T p.Q461* (on ENST00000316577 / NM_001098815.3; = p.Q323* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 125/230 reads (54%) | catalogued as COSV100345040; called by muse, mutect2, varscan2
- TNR | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 157/212 reads (74%) | catalogued as COSV99688631; called by muse, mutect2, varscan2
- TREM1 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV99776130; called by muse, mutect2, varscan2
- TRIO | c.2699G>T p.R900L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100710125; called by muse, mutect2, varscan2
- TSGA10IP | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100408945; called by muse, mutect2, varscan2
- TTC8 | c.1336C>G p.H446D (on ENST00000338104 / NM_001288781.1; = p.H430D on NM_144596.4) | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100581195; called by muse, mutect2, varscan2
- TTN | c.88285T>C p.C29429R (on ENST00000591111; = p.C22005R on NM_003319.4) | Missense Mutation (SNP) | VAF 73/287 reads (25%) | PolyPhen probably damaging (0.931); catalogued as COSV100602446; called by muse, mutect2, varscan2
- TTN | c.41963A>C p.K13988T (on ENST00000591111; = p.K6564T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | PolyPhen benign (0.009); catalogued as COSV100602451; called by muse, mutect2
- TTN | c.23357G>C p.G7786A (on ENST00000591111; = p.G6859A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100602461, COSV59878438; called by muse, mutect2, varscan2
- TTN | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | PolyPhen possibly damaging (0.807); catalogued as rs200848334; called by muse, mutect2, varscan2
- UNC13C | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52933512, COSV99514178; called by muse, mutect2, varscan2
- UPK2 | c.124del p.E42Rfs*19 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as COSV99875049; called by mutect2, pindel, varscan2
- VAV1 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 75/87 reads (86%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs1295017027, COSV100408820; called by muse, mutect2, varscan2
- VOPP1 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as rs760304705, COSV53390368, COSV99567080; called by muse, varscan2
- VPS13D | c.10661A>T p.D3554V | Missense Mutation (SNP) | VAF 85/111 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165923; called by muse, mutect2, varscan2
- WNK3 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1161469441, COSV100671060; called by muse, mutect2, varscan2
- ZADH2 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100463348; called by muse, mutect2, varscan2
- ZEB1 | c.2315G>T p.C772F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as COSV100313994; called by muse, mutect2, varscan2
- ZGLP1 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV100593725; called by muse, mutect2, varscan2
- ZNF181 | c.1193T>C p.I398T | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1427136320, COSV101106239; called by muse, mutect2, varscan2
- ZNF185 | c.1220A>T p.D407V | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100248297; called by muse, mutect2, varscan2
- ZNF33A | c.2350T>C p.F784L (on ENST00000458705 / NM_006974.3; = p.F785L on NM_006954.2) | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100275633; called by muse, mutect2
- ZNF34 | c.806A>G p.H269R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100603248; called by muse, mutect2
- ZNF470 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV100401156; called by muse, mutect2, varscan2
- ZNF536 | c.3280G>T p.G1094C | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100834940, COSV62820492, COSV62827080; called by muse, mutect2, varscan2
- ZZEF1 | c.6123T>G p.I2041M | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.063); catalogued as COSV101067666; called by muse, mutect2, varscan2
- A2ML1 | c.3510_3539del p.I1171_S1180del | In Frame Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- ACACB | c.5756_5759del p.S1919Wfs*12 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- AKR1A1 | c.286_287del p.R96Efs*5 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.2619_2633del p.M873_G877del | In Frame Del (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- IGLC7 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.282_285del p.K94Nfs*14 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- LGALS4 | c.74_78del p.G25Afs*43 | Frame Shift Del (DEL) | VAF 80/101 reads (79%) | called by mutect2, pindel, varscan2
- LRRK2 | c.3916_3928del p.F1306Ifs*2 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, varscan2
- SCN9A | c.5550_5551insTT p.G1851Lfs*35 (on ENST00000303354; = p.G1840Lfs*35 on NM_002977.3) | Frame Shift Ins (INS) | VAF 65/204 reads (32%) | called by mutect2, pindel*, varscan2
- SMC1B | c.244del p.I82Lfs*31 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- ST6GALNAC5 | c.921_924dup p.R309Gfs*24 | Frame Shift Ins (INS) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- STAT4 | c.94del p.H32Ifs*30 | Frame Shift Del (DEL) | VAF 46/121 reads (38%) | called by mutect2, pindel, varscan2
- SYNE1 | c.15221_15244del p.K5074_R5081del (on ENST00000367255 / NM_182961.4; = p.K5003_R5010del on NM_033071.3) | In Frame Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel
- ABRAXAS2 | c.1014C>A p.G338= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100044905; called by muse, varscan2
- ADAMTS20 | c.3841C>T p.L1281= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV101166145; called by muse, mutect2, varscan2
- ALDH8A1 | c.1377G>A p.G459= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99664569; called by muse, mutect2, varscan2
- CASP10 | c.798T>G p.S266= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV99628879; called by muse, mutect2
- CCT8L2 | c.1362G>A p.E454= | Silent (SNP) | VAF 93/192 reads (48%) | catalogued as COSV100742630, COSV63461665; called by muse, mutect2, varscan2
- CDC7 | c.1500C>T p.L500= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as rs1312419240, COSV99319643; called by muse, mutect2, varscan2
- CDH18 | c.2316C>A p.P772= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV99933290; called by muse, mutect2, varscan2
- CFAP91 | c.1644G>C p.L548= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99846974; called by muse, mutect2
- CPN2 | c.288G>T p.L96= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100102983; called by muse, mutect2, varscan2
- CRISP3 | c.477G>T p.G159= (on ENST00000371159 / NM_001368123.1; = p.G141= on NM_006061.4) | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV99538793; called by muse, mutect2, varscan2
- CSMD3 | c.7641T>G p.L2547= (on ENST00000297405 / NM_001363185.1; = p.L2443= on NM_052900.3) | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV99829622; called by muse, mutect2
- CTNNA3 | c.2523C>A p.P841= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV65525722; called by muse, mutect2, varscan2
- DDR2 | c.495G>C p.R165= | Silent (SNP) | VAF 104/161 reads (65%) | catalogued as COSV100906362; called by muse, mutect2, varscan2
- DNAJB11 | c.804G>A p.E268= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs939670757, COSV99408579; called by muse, mutect2
- DPP7 | c.405G>C p.L135= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV100857321; called by muse, varscan2
- EBF3 | c.657C>A p.V219= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100799115; called by muse, mutect2, varscan2
- EGR2 | c.825C>G p.G275= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV54346554, COSV99654049; called by muse, mutect2, varscan2
- ESS2 | c.633C>T p.A211= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as COSV99350734; called by muse, mutect2, varscan2
- ESYT1 | c.1884G>C p.V628= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99919838; called by muse, mutect2, varscan2
- FBXW5 | c.1182G>A p.A394= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV56403618; called by muse, mutect2, varscan2
- FKBP9 | c.1417C>T p.L473= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99639294; called by muse, mutect2, varscan2
- HIVEP3 | c.5463C>T p.A1821= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs1279057683, COSV99912007; called by muse, mutect2, varscan2
- HYDIN | c.1165A>C p.R389= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99862499; called by muse, mutect2, varscan2
- IGDCC3 | c.1701C>A p.T567= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100030945; called by muse, mutect2, varscan2
- IGKV1-9 | c.216T>A p.A72= | Silent (SNP) | VAF 170/346 reads (49%) | catalogued as rs769266655; called by muse, mutect2, varscan2
- INSL6 | c.603A>G p.L201= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as rs759221356, COSV101068454; called by muse, mutect2, varscan2
- KALRN | c.5724G>C p.G1908= (on ENST00000360013 / NM_001024660.4; = p.G211= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV99361557; called by muse, mutect2, varscan2
- KCNK13 | c.1131G>A p.Q377= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99965589; called by muse, mutect2, varscan2
- MAGEB10 | c.486G>T p.L162= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV100775223; called by muse, mutect2, varscan2
- MRGPRD | c.267C>A p.P89= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV100482963, COSV58424144; called by muse, mutect2, varscan2
- MRGPRX1 | c.618C>A p.S206= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100245915; called by muse, mutect2, varscan2
- MUC17 | c.6318T>C p.S2106= | Silent (SNP) | VAF 181/435 reads (42%) | catalogued as COSV100072470; called by muse, mutect2, varscan2
- NOS1 | c.387C>A p.P129= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1050514291, COSV100500300; called by muse, mutect2, varscan2
- OR4K2 | c.360T>C p.F120= | Silent (SNP) | VAF 68/288 reads (24%) | catalogued as COSV100064286; called by muse, mutect2, varscan2
- OR52A1 | c.348C>T p.I116= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV61093062; called by muse, mutect2, varscan2
- OR5B3 | c.234C>T p.I78= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs762934435, COSV100512040, COSV58679008; called by muse, mutect2, varscan2
- OR5H15 | c.474C>A p.I158= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV62948990, COSV62949008; called by muse, mutect2
- OR5L1 | c.75C>A p.V25= | Silent (SNP) | VAF 94/243 reads (39%) | catalogued as COSV100449984; called by muse, varscan2
- OR5L1 | c.141A>T p.A47= | Silent (SNP) | VAF 124/304 reads (41%) | catalogued as COSV100449985, COSV61734617; called by muse, varscan2
- OR6B1 | c.357C>G p.A119= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs770081905, COSV101281643, COSV68769769; called by muse, mutect2, varscan2
- PCDHGB3 | c.957G>C p.V319= | Silent (SNP) | VAF 65/90 reads (72%) | catalogued as COSV99534208; called by muse, mutect2, varscan2
- PRKDC | c.1992T>C p.S664= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV100039367; called by muse, mutect2, varscan2
- RALGDS | c.2241G>A p.P747= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as rs746484523, COSV100924336; called by muse, mutect2
- RNF20 | c.636G>C p.L212= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV100874309; called by muse, mutect2, varscan2
- SASH1 | c.930G>A p.V310= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100821068; called by muse, mutect2, varscan2
- SH2D4B | c.769C>A p.R257= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100213707; called by muse, mutect2, varscan2
- SLC9C1 | c.1890C>A p.I630= | Silent (SNP) | VAF 75/318 reads (24%) | catalogued as rs1413170338, COSV99997620; called by muse, mutect2, varscan2
- SMG1 | c.3918G>A p.P1306= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1487624173, COSV101245500; called by muse, mutect2
- SPAG17 | c.372G>T p.L124= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100308538; called by muse, mutect2, varscan2
- STARD13 | c.1014C>T p.H338= (on ENST00000336934 / NM_001243476.3; = p.H220= on NM_052851.3) | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV55227630; called by muse, mutect2, varscan2
- STIP1 | c.633A>G p.P211= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as rs1011304151, COSV100534813; called by muse, mutect2, varscan2
- TEX55 | c.456C>T p.T152= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1229179401, COSV99817400; called by muse, mutect2, varscan2
- TRAV34 | c.93G>A p.L31= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1483226078; called by muse, mutect2, varscan2
- TSPAN19 | c.552A>G p.R184= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV101468077; called by muse, mutect2, varscan2
- TUBA3E | c.909C>G p.V303= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as COSV56058617; called by muse, mutect2
- VSTM2A | c.114G>A p.A38= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs1391600011, COSV56494387; called by muse, mutect2, varscan2
- ZMIZ2 | c.2049G>T p.V683= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV54810283, COSV99536719; called by muse, mutect2, varscan2
- ZNF781 | c.348T>G p.P116= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV100669183; called by muse, mutect2, varscan2
- ZZZ3 | c.732T>C p.D244= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs777066570, COSV100890257; called by muse, mutect2, varscan2
- AC073310.1 | n.155A>G | RNA (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- AC073310.1 | n.327G>A | RNA (SNP) | VAF 153/372 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.1260G>A | RNA (SNP) | VAF 21/30 reads (70%) | catalogued as COSV100251371; called by muse, mutect2, varscan2
- HLA-L | n.920G>T | RNA (SNP) | VAF 123/181 reads (68%) | called by muse, mutect2, varscan2
- ITGA3 | c.*122G>C | 3'UTR (SNP) | VAF 147/167 reads (88%) | catalogued as rs761956618, COSV50327606, COSV99143458; called by muse, mutect2, varscan2
- SSPOP | n.14574C>G | RNA (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100947190, COSV65127692; called by muse, mutect2, varscan2
- TMEM105 | n.680C>T | RNA (SNP) | VAF 22/146 reads (15%) | catalogued as rs374207720; called by muse, mutect2, varscan2
- TNK2 | c.-18-6713C>T | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as COSV57370200; called by muse, mutect2, varscan2
